Somatic mutation profile of tumor specimen ALCH-AE8L-TTP1-A (aliquot ALCH-AE8L-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AE8L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.1 years (25,590 days).
Specimen ALCH-AE8L-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34d4322f-3373-4410-809f-91d61a2ba4ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE8L-NB1-A (Blood Derived Normal), aliquot ALCH-AE8L-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b75f60f6-d665-4f14-8f83-c9c4c0c2d5fc

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, 3'UTR 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH1B | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs187446108, COSV104396458; called by muse, mutect2
- DGKK | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs187535842, COSV65707595; called by muse, mutect2
- DNAH10 | c.2950C>T p.R984W (on ENST00000409039; = p.R923W on NM_207437.3) | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs138047908; called by muse, mutect2
- FOXP2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 50/808 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1276471970, COSV63486447; called by muse, mutect2
- KSR2 | c.2560C>T p.H854Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as rs1265534568; called by muse, mutect2, varscan2
- NEBL | c.2858C>T p.S953L | Missense Mutation (SNP) | VAF 38/715 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs1383928349; called by muse, mutect2
- NETO1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 23/425 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as rs1191425947, COSV55002344; called by muse, mutect2
- RP1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 26/481 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs760561079, CD098189, COSV99607023; called by muse, mutect2
- ZNF99 | c.559C>A p.H187N | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV68056457; called by muse, mutect2
- ZWINT | c.266C>G p.A89G | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100571514; called by muse, mutect2
- ABCA13 | c.12850C>T p.L4284F | Missense Mutation (SNP) | VAF 41/438 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- DEF6 | c.1640T>C p.M547T | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- ICE2 | c.2608T>G p.S870A | Missense Mutation (SNP) | VAF 23/263 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- KIF4A | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 40/591 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- MED12 | c.6001C>T p.Q2001* | Nonsense Mutation (SNP) | VAF 17/231 reads (7%) | called by muse, mutect2
- MICA | c.155A>T p.D52V | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAA15 | c.1527T>G p.H509Q | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- XIRP2 | c.8690A>C p.N2897T (on ENST00000628543; = p.N3072T on NM_152381.6) | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- CEP20 | c.117C>T p.D39= | Silent (SNP) | VAF 30/584 reads (5%) | catalogued as COSV99739921; called by muse, mutect2
- HERC2 | c.3285C>A p.L1095= | Silent (SNP) | VAF 13/355 reads (4%) | catalogued as COSV55342860; called by muse, mutect2
- IL16 | c.2943C>T p.D981= (on ENST00000302987 / NM_172217.5; = p.D280= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/340 reads (6%) | catalogued as rs575809541, COSV100267364; called by muse, mutect2
- LTBP1 | c.3783C>T p.D1261= (on ENST00000404816 / NM_206943.4; = p.D935= on NM_000627.4) | Silent (SNP) | VAF 9/221 reads (4%) | catalogued as COSV55386503; called by muse, mutect2
- PCDHB3 | c.360G>A p.E120= | Silent (SNP) | VAF 26/292 reads (9%) | catalogued as rs547899655; called by muse, mutect2
- SERPINA6 | c.78C>T p.N26= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as rs758471605; called by muse, mutect2
- SLC6A5 | c.1170C>T p.G390= | Silent (SNP) | VAF 54/604 reads (9%) | catalogued as rs369546941; called by muse, mutect2
- TMPO | c.1302G>A p.E434= | Silent (SNP) | VAF 40/516 reads (8%) | called by muse, mutect2
- TSHZ3 | c.2551C>T p.L851= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV53663948; called by muse, mutect2
- TNFRSF10B | c.*230G>A | 3'UTR (SNP) | VAF 34/594 reads (6%) | called by muse, mutect2
- TTC3P1 | n.4826A>G | RNA (SNP) | VAF 22/336 reads (7%) | called by muse, mutect2
